Somatic mutation profile of tumor specimen ALCH-B3KQ-TTP1-A (aliquot ALCH-B3KQ-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3KQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.2 years (21,272 days).
Specimen ALCH-B3KQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9998854a-a167-4da4-ba39-9acd1fa52a66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3KQ-NB1-A (Blood Derived Normal), aliquot ALCH-B3KQ-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3a2cb47-413a-4eae-8a51-9a6c0c46b220

The open-access MAF lists 76 somatic variants for this specimen: 55 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 13, Intron 3, RNA 3, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.4997G>A p.R1666H | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs121908216, CM992138; ClinVar: likely pathogenic; called by mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 275/864 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 96/342 reads (28%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANO2 | c.1378A>T p.M460L (on ENST00000356134 / NM_001278597.3; = p.M464L on NM_001278596.3) | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs1305960853; called by mutect2, varscan2
- CCER2 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as rs981616631; called by muse, mutect2, varscan2
- CD22 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.161); catalogued as rs756111081, COSV50056700; called by muse, mutect2, varscan2
- CIITA | c.2951C>T p.S984F | Missense Mutation (SNP) | VAF 186/1091 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV60861457; called by muse, mutect2, varscan2
- CNGB3 | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 105/739 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201881873, COSV60687200; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL14A1 | c.3910G>T p.A1304S | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); catalogued as rs776282364; called by muse, mutect2, varscan2
- FAM13A | c.1804C>G p.R602G | Missense Mutation (SNP) | VAF 84/645 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV52010446; called by muse, mutect2, varscan2
- FRMPD1 | c.4328G>A p.G1443E | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); catalogued as COSV100899597; called by muse, mutect2, varscan2
- GUSB | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 78/448 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs752854143, COSV100512699; ClinVar: likely benign; called by muse, mutect2, varscan2
- HECW1 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 26/373 reads (7%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs531733998, COSV67838523; called by muse, mutect2
- KLC1 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 49/364 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99871568; called by muse, mutect2, varscan2
- LAIR1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 42/361 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1334859911, COSV57307621; called by muse, mutect2, varscan2
- LAMA4 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 147/666 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377633183, COSV57894262; called by muse, mutect2, varscan2
- NPR1 | c.2915G>A p.R972H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417289428; called by muse, mutect2
- OR2F2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as rs1175463741, COSV101283832, COSV68832872; called by muse, mutect2, varscan2
- PTPRZ1 | c.5264G>A p.R1755Q | Missense Mutation (SNP) | VAF 65/568 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs757941062, COSV66445597; called by muse, mutect2, varscan2
- RIMS1 | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 86/938 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV53447084; called by muse, mutect2
- ROBO3 | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as rs1187851055; called by muse, varscan2
- SALL1 | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51761173; called by muse, mutect2
- SHANK2 | c.4151C>T p.A1384V | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as rs782510001, COSV53584445; called by muse, mutect2
- SRRM2 | c.4226C>A p.A1409D | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as rs141353583, COSV100070236; called by muse, mutect2
- TMEM176A | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 26/424 reads (6%) | catalogued as rs971196931; called by muse, mutect2
- WDFY4 | c.6898C>T p.R2300C | Missense Mutation (SNP) | VAF 66/534 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs570644020; called by muse, mutect2, varscan2
- AKR7A3 | c.871A>C p.S291R | Missense Mutation (SNP) | VAF 36/514 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ANKUB1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 56/593 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.01); called by muse, mutect2
- APBB1IP | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ARHGEF18 | c.3336C>A p.S1112R (on ENST00000359920 / NM_001130955.2; = p.S1008R on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- BBX | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- BGN | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- CACTIN | c.1645C>G p.Q549E | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH23 | c.9612C>G p.I3204M | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- CFAP45 | c.215T>G p.L72W | Missense Mutation (SNP) | VAF 46/432 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTPD6 | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ERCC8 | c.1244G>T p.G415V (on ENST00000265038; = p.G396V on NM_000082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/722 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ESCO1 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FSIP2 | c.19261G>C p.V6421L | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2
- GRIN3A | c.1837T>A p.W613R | Missense Mutation (SNP) | VAF 78/852 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIN3A | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 86/456 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KRT9 | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- MINK1 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR5K2 | c.686A>T p.K229I | Missense Mutation (SNP) | VAF 53/426 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLR2B | c.2278_2286del p.T760_R762del | In Frame Del (DEL) | VAF 77/435 reads (18%) | called by mutect2, pindel, varscan2
- RNF17 | c.4260C>G p.H1420Q | Missense Mutation (SNP) | VAF 67/445 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO2 | c.904dup p.M302Nfs*35 | Frame Shift Ins (INS) | VAF 133/937 reads (14%) | called by mutect2, pindel, varscan2
- SCN9A | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SEPTIN14 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 61/565 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SHB | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC34A2 | c.1597C>A p.L533M | Missense Mutation (SNP) | VAF 68/653 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- WAC | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 82/892 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2
- WDR87 | c.4620T>A p.D1540E | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.155); called by muse, mutect2
- ZEB2 | c.2543G>C p.S848T | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZKSCAN4 | c.1529C>G p.T510S | Missense Mutation (SNP) | VAF 31/437 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- C5orf49 | c.102G>T p.R34= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- CACNA1S | c.4572C>T p.Y1524= | Silent (SNP) | VAF 66/1257 reads (5%) | catalogued as rs765581827, COSV62937607; ClinVar: likely benign; called by muse, mutect2
- CCDC178 | c.516T>C p.R172= | Silent (SNP) | VAF 62/604 reads (10%) | called by muse, mutect2
- CLDN8 | c.213G>T p.L71= | Silent (SNP) | VAF 17/171 reads (10%) | called by muse, mutect2, varscan2
- DENND1C | c.2379T>C p.A793= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- FBXL18 | c.831C>T p.G277= | Silent (SNP) | VAF 26/177 reads (15%) | catalogued as COSV66668494; called by muse, mutect2, varscan2
- KCNJ15 | c.168C>T p.T56= | Silent (SNP) | VAF 159/528 reads (30%) | called by muse, mutect2, varscan2
- KRI1 | c.1074G>A p.R358= | Silent (SNP) | VAF 53/152 reads (35%) | catalogued as rs1355133111; called by muse, mutect2, varscan2
- LAMA2 | c.2661G>T p.L887= | Silent (SNP) | VAF 60/1235 reads (5%) | called by muse, mutect2
- NEUROD1 | c.615C>A p.P205= | Silent (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- PRDM9 | c.240C>T p.A80= | Silent (SNP) | VAF 68/1122 reads (6%) | called by muse, mutect2
- SLC12A3 | c.957C>T p.S319= | Silent (SNP) | VAF 26/291 reads (9%) | called by muse, mutect2
- SMG1 | c.231C>T p.H77= | Silent (SNP) | VAF 80/2070 reads (4%) | catalogued as rs766273844, COSV67172429; called by muse, mutect2
- ASH1L | chr1:155563364 T>A | 5'Flank (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- CKS2 | c.-62G>A | 5'UTR (SNP) | VAF 40/255 reads (16%) | catalogued as rs951770925; called by muse, mutect2, varscan2
- FAM205BP | n.2236A>G | RNA (SNP) | VAF 112/1128 reads (10%) | called by muse, mutect2
- LRRFIP1 | c.250-9059del | Intron (DEL) | VAF 25/220 reads (11%) | called by mutect2, pindel, varscan2
- OR52A4P | n.983T>C | RNA (SNP) | VAF 10/86 reads (12%) | catalogued as rs1404561047; called by muse, mutect2, varscan2
- PABPC1P2 | n.997T>C | RNA (SNP) | VAF 82/794 reads (10%) | catalogued as rs560398337; called by muse, mutect2
- TMEM255B | c.190-917C>T | Intron (SNP) | VAF 56/187 reads (30%) | catalogued as rs994133532; called by muse, mutect2, varscan2
- UGP2 | c.148-260T>C | Intron (SNP) | VAF 97/510 reads (19%) | called by muse, varscan2
